Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8KE, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8KE-01A (Primary Tumor).

[page 1 of 3]
printed:

UUID: C9CCC817-9FA1-401A-A075-28280AB10207 TCGA-VD-A8KE-01A-PR		Page 1 of 3
Redacted  		REPORT Tel:
Forename 	Sex 	Clinical Consultant & Location
Unit No 		

This Copy For:

SPECIMEN

Left enucleation

CLINICAL DETAILS

Collar stud appearance. Intrinsic vessels.

MACROSCOPIC DESCRIPTION

An intact left eye.

Dimensions: axial 24mm, horizontal 24mm, vertical 22mm.

Cornea: horizontal 12mm, vertical 11mm.

Optic nerve: cut flush.

Pupil: regular.

On trans-illumination, a shadow is seen laterally at posterior pole measuring 9mm in maximum dimension.

Plane of section: horizontal.

A pigmented collar-stud choroidal tumour is confirmed.

Tumour size: LBD 8mm, Height 9mm.

Sections show a focally pigmented choroidal melanoma with attached adjacent normal choroid and sclera. The tumour is of mixed cell type (approximate 60% of epithelioid cells). The number of mitosis is approximately 3/40 high power fields. The microvasculature of the melanoma is prominent, and closed loops are present in the planes of section. The lymphocytic infiltrate within the tumour is minimal. Tumour necrosis is not seen. There is focal early scleral invasion but no tumour extension through optic nerve or vortex veins examined is seen. Tumour cells are not seen at the resection margins.

Elsewhere, the cornea shows no significant abnormality. Hassall-Henle warts are noted. The anterior chamber angles are open but the anterior chamber is shallow. The iris shows

ICD-O-3
Melanoma, epithelioid + spindle cell
mixed 8776/3
Site @ Choroid C69.3
9/11/14

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

no significant abnormality, and the ciliary body appears atrophic with hyalinisation of ciliary processes. The lens shows peripheral degeneration. Retina overlying the tumour is slightly atrophic and Bruch's membrane appears breached in the sections examined. Several drusen are seen. Optic nerve cupping is also noted.

DIAGNOSIS

Left enucleation - Choroidal melanoma of mixed cell type

COMMENT

Assessment of immunohistochemistry for MelanA and HSP 27 will follow. In addition, molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8.

A supplementary report will follow in due course.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	3= Mixed
CT LOOPS	2= Closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	3/40 HPF
DIFFUSE MELANOMA	No
SPREAD	2= Intra-scleral (focal)
CLEARANCE	2= Adequate

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]		Sex [REDACTED]
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

HSP-27 POSITIVITY To follow

LARGE DIAMETER 8 mm
THICKNESS 9 mm

Supplementary Report

HSP-27 POSITIVITY 3 = >70%

SUPPLEMENTARY REPORT - MOLECULAR PATHOLOGY

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED] which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report. In summary, sequence analysis demonstrated:

normal chromosome 1, essentially normal chromosome 3 (2 borderline losses), gains in chromosome 6 and normal chromosome 8.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

Source: NCI Genomic Data Commons file faf1a002-c613-4cea-aa3b-1676d95501c9 (TCGA-VD-A8KE.C9CCC817-9FA1-401A-A075-282B0AB10207.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).